Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A6GX, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A6GX-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology

Final Results

CASE NUMBER:

DIAGNOSIS: Adrenal gland, right, adrenalectomy: Pheochromocytoma.
Areas suspicious for vascular invasion are present.

NOTE: Immunohistochemical studies demonstrate tumor cells staining positively for chromogranin and synaptophysin with focal positivity for P53 and negative staining for c-Kit. The tumor shows an intermediate proliferative index by MIB-1 staining.

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the . They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Allocate Order to Protocol: Brief
Clinical History: F s/p
R adrenalectomy for pheo Specimen Taken For Protocol - Yes

PROCEDURE: Pre-Operative Diagnosis: pheo Post-Operative Diagnosis: same
Operative Findings: large R adrenal tumor

SPECIMENS SUBMITTED: 1. ADRENAL GLAND, RIGHT

GROSS DESCRIPTION: Received fresh in a container labeled with the patient's name, medical record number, and further specified "right adrenal gland 3 x 5 cm" is an adrenal gland with minimal attached fat measuring 5.5 x 4.2 x 3.0 cm and weighing 28.5 grams. There is a solitary nodule, 4.2 x 4.2 x 3 cm. The external surface is inked black. The nodule is bisected revealing a pink-gray, fleshy cut surface arising from the medulla. There is normal-appearing adrenal gland, compressed on either side of the nodule. Gross photographs are taken. Approximately 45% of the tissue is procured from the center of the nodule for Dr. and 1% is procured from the center of the nodule for Dr.

The remainder of the specimen is placed into formalin and submitted to Pathology for permanent processing. Received in Surgical Pathology is a specimen matching the above description, consisting of a bisected adrenal gland with external surface inked in black. The specimen is entirely bisected and one-half of the specimen is further bisected along the longitudinal axis to include the overlying normal thyroid tissue and representative sections are submitted into cassettes labeled A, B and C. The other one-half of the specimen is serially sectioned in 3 mm increments along the short axis and representative sections are submitted into cassettes labeled D, E, F, G, H, I, and J. The remainder of the specimen is returned to formalin.

Requested By:

Do not file in Medical Record

[page 2 of 2]
Gross Description dictated by

Accessioned:

Final Report Signed Out:

<Resident Signature>

<Sign Out Dr. Signature>

Date Report Signed:

Requested By:

Do not file in Medical Record

Source: NCI Genomic Data Commons file 43cf0136-1a39-4e0b-badd-0776cc7938c7 (TCGA-QR-A6GX.4FEB8AC0-BA60-40FC-86D4-112FD99B11A8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).